Somatic mutation profile of tumor specimen TCGA-V4-A9EL-01A (aliquot TCGA-V4-A9EL-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EL, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.6 years (22,150 days).
Specimen TCGA-V4-A9EL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab6a7bf9-92af-4949-922a-0338696374ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EL-10A (Blood Derived Normal), aliquot TCGA-V4-A9EL-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/977d5ea7-bcc2-4543-9031-de09dc91430e

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 55/129 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SYTL3 | c.1330G>A p.V444I (on ENST00000611299 / NM_001242394.1; = p.V376I on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/66 reads (71%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs749669847, COSV51908623; called by muse, mutect2, varscan2
- EWSR1 | c.258C>G p.Y86* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- LRP1B | c.10231C>T p.P3411S | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF473 | c.1934del p.P645Lfs*22 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- SERPINB4 | c.894G>A p.T298= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs776882459, COSV61984620; called by muse, mutect2, varscan2
- WDR47 | c.891C>G p.S297= | Silent (SNP) | VAF 139/367 reads (38%) | called by muse, mutect2, varscan2
